Gene-level copy-number profile of tumor specimen TCGA-55-6979-01A from TCGA case TCGA-55-6979, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.6 years (21,780 days).
Specimen TCGA-55-6979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5a1570e5-e739-4d96-9d3f-17b178d3b069.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6979-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fbb73eae-06c9-4502-beb4-a58e1c7e5394

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,344; copy number 2: 37,253; copy number 3: 3,537; copy number 4: 1,381; copy number 5: 299.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6979-01A-11D-1943-01): tumor purity 0.33, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 299 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:28,435,388–31,466,431, 57 genes, copy number 5: AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1.
- chr19:32,405,543–36,246,257, 191 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:39,685,244–40,765,389, 51 genes, copy number 5: AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA.

Autosomal genes at a single copy (total copy number 1): 17,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
